Somatic mutation profile of tumor specimen MP2PRT-PAVEVB-TMP1-A (aliquot MP2PRT-PAVEVB-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVEVB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,296 days).
Specimen MP2PRT-PAVEVB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e82b630a-4151-4ebe-af3b-5a7bdd0364f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVEVB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVEVB-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd150508-c85d-4c4c-97c1-709821844d2b

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.7257C>A p.F2419L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99262987; called by muse, mutect2, varscan2
- ARHGEF6 | c.1060C>A p.Q354K | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs769789476; called by muse, mutect2, varscan2
- OLFM1 | c.1042G>A p.A348T (on ENST00000371793 / NM_001282611.2; = p.A330T on NM_014279.5) | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.385); catalogued as COSV53280488; called by muse, mutect2, varscan2
- PLPP4 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1029033900; called by muse, mutect2, varscan2
- SAMD9L | c.3595G>A p.G1199S | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV100560311; called by muse, mutect2, varscan2
- SHD | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 89/316 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.372); catalogued as COSV73378702; called by muse, mutect2, varscan2
- LRRTM4 | c.170A>G p.E57G | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MAN2B2 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 15/305 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.038); called by muse, mutect2
- NSMCE4A | c.398A>G p.D133G | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB1 | c.1000G>C p.V334L | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SOX5 | c.1091A>G p.N364S | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- UNC93B1 | c.696C>A p.F232L | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PAX9 | c.183C>T p.N61= | Silent (SNP) | VAF 94/395 reads (24%) | catalogued as rs1222366464; called by muse, mutect2, varscan2
- SLC4A10 | c.405A>C p.R135= | Silent (SNP) | VAF 24/246 reads (10%) | called by muse, mutect2
